Somatic mutation profile of tumor specimen TCGA-EL-A3T9-01A (aliquot TCGA-EL-A3T9-01A-21D-A22D-08) from TCGA case TCGA-EL-A3T9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.8 years (25,484 days).
Specimen TCGA-EL-A3T9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9099ed-c5bd-426f-b20f-ad48af6e25ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T9-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T9-11A-11D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d199e11f-4581-4010-91f2-6342d56e1689

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 14, Silent 10.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.372A>T p.E124D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as COSV55737583; called by muse, mutect2, varscan2
- CFAP251 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1419713838, COSV55839310; called by muse, mutect2, varscan2
- COL6A2 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs760395633, COSV56003443; called by muse, mutect2, varscan2
- ETS1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60093056; called by muse, mutect2, varscan2
- FLNC | c.6646G>A p.D2216N | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV57954583; called by muse, mutect2, varscan2
- IGLV8-61 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs542479842, COSV66502625; called by muse, mutect2, varscan2
- ITGAL | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63321807; called by muse, mutect2, varscan2
- MPPED1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.465); catalogued as rs749571377, COSV61987482; called by mutect2, varscan2
- NTRK3 | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV58118882, COSV58121441; called by muse, mutect2, varscan2
- PCSK1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1160330138, COSV60734812; called by muse, mutect2, varscan2
- SEZ6L | c.1300A>C p.I434L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50661931; called by muse, mutect2, varscan2
- SLC25A33 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV57019918; called by muse, mutect2, varscan2
- SLC8A1 | c.2547C>A p.D849E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60478255; called by muse, mutect2, varscan2
- STOML2 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59715751; called by muse, mutect2, varscan2
- AP5Z1 | c.2394G>T p.V798= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs765742740, COSV62241405; called by muse, mutect2, varscan2
- CAPS | c.480G>A p.A160= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs371122890; called by muse, mutect2, varscan2
- EFNB1 | c.726G>A p.A242= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs748930955, COSV52661496; called by muse, mutect2, varscan2
- ELFN2 | c.2370C>T p.H790= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as rs148494870; called by muse, mutect2, varscan2
- GJA8 | c.498C>A p.I166= | Silent (SNP) | VAF 120/294 reads (41%) | catalogued as COSV53788642, COSV53788663; called by muse, mutect2, varscan2
- GPR135 | c.1068C>T p.A356= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV67749579; called by muse, mutect2, varscan2
- ITGA6 | c.138C>T p.F46= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs377085042, COSV51223007; called by muse, mutect2, varscan2
- KIAA1109 | c.7170C>T p.P2390= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs773326319, COSV52669839; called by muse, mutect2, varscan2
- SMCO1 | c.357A>G p.R119= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV58837370; called by muse, mutect2, varscan2
- ZNF414 | c.630C>T p.P210= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs766626003, COSV55321517; called by muse, mutect2
